Somatic mutation profile of tumor specimen TARGET-10-PATCDM-09A (aliquot TARGET-10-PATCDM-09A-01D) from TARGET case TARGET-10-PATCDM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,192 days).
Specimen TARGET-10-PATCDM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69415ac5-0134-47d4-8c84-965028f0250f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATCDM-10A (Blood Derived Normal), aliquot TARGET-10-PATCDM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ee290f0-52e7-48c2-ba91-8001c00c2309

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 2, Nonsense Mutation 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CXXC1 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV53275262; called by muse, mutect2, varscan2
- DNAH10 | c.2626G>T p.E876* (on ENST00000409039; = p.E815* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 9/12 reads (75%) | catalogued as COSV68996033; called by muse, mutect2, varscan2
- EVI2A | c.700C>G p.Q234E | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV55986331; called by muse, mutect2, varscan2
- USP7 | c.2384_2386del p.D795del | In Frame Del (DEL) | VAF 45/88 reads (51%) | called by mutect2, pindel, varscan2
- AKR1C4 | c.285C>A p.V95= | Silent (SNP) | VAF 7/141 reads (5%) | catalogued as COSV54123185; called by muse, mutect2
- EFNA2 | c.516G>A p.P172= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as rs377098217; called by muse, mutect2
- SIPA1 | c.3117C>T p.A1039= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs780236671; called by muse, mutect2, varscan2
- TBCD | c.3282-108A>C | Intron (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
